Somatic mutation profile of tumor specimen TARGET-10-PAPFZX-09A (aliquot TARGET-10-PAPFZX-09A-01D) from TARGET case TARGET-10-PAPFZX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,177 days).
Specimen TARGET-10-PAPFZX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f1c464e-4d18-411a-9e90-d012866c3577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFZX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFZX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0622fd8-2230-42df-94a6-1eef16fd82bd

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC5 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs878854279, COSV56692622, COSV56693027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN2 | c.13042C>T p.R4348W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs766771569; called by muse, mutect2, varscan2
- BAG6 | c.3394G>C p.A1132P (on ENST00000676571; = p.A1085P on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- OR51B4 | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF34 | c.634-1G>T p.X212_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- UTP20 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DENND1A | c.1149T>C p.D383= | Silent (SNP) | VAF 56/133 reads (42%) | called by muse, mutect2, varscan2
- NOL10 | c.1203G>A p.G401= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
